Gene-level copy-number profile of tumor specimen TCGA-DM-A1D6-01A from TCGA case TCGA-DM-A1D6, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Splenic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DM-A1D6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.c45a2b48-2777-4a68-9aa3-41967c509406.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A1D6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 370 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5416b91e-c75c-45db-b043-65595dde1e2c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 506; copy number 1: 13,640; copy number 2: 40,532; copy number 3: 5,203; copy number 4: 147; copy number 5: 87; copy number 7: 25; copy number 8: 3; copy number 9: 4; copy number 14: 23; copy number 17: 34; copy number 19: 37; copy number 26: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A1D6-01A-21D-A151-01): tumor purity 0.9, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,881,363–242,078,722, 1 gene (within-gene range 0–2): LINC01237.
- chr2:242,001,209–242,160,153, 8 genes: AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr16:5,838,131–6,092,954, 3 genes: AC012175.1, AC009135.2, AC009135.1.
- chr16:6,573,767–6,577,359, 1 gene: AC007223.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 225 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 7 (within-gene range 2–7): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 7: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr8:126,556,323–127,419,050, 1 gene, copy number 8 (within-gene range 1–17): PCAT1.
- chr8:126,671,522–127,227,541, 3 genes, copy number 8–14 (within-gene range 1–14): RNU11-4P, AC024382.1, CASC19.
- chr8:127,253,213–134,979,279, 109 genes, copy number 9–26 (within-gene range 9–31) (broad region; genes not listed).
- chr14:18,333,726–19,936,757, 82 genes, copy number 5 (broad region; genes not listed).
- chr14:73,189,763–73,274,640, 5 genes, copy number 5: AC004858.1, PAPLN, AC004846.1, RNU6-419P, AC004846.2.

Autosomal genes at a single copy (total copy number 1): 11,194. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
